Somatic mutation profile of tumor specimen ALCH-B35B-TTP1-A (aliquot ALCH-B35B-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B35B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.5 years (19,163 days).
Specimen ALCH-B35B-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba2ff652-10e5-4ac5-ab11-b102f7e99a2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B35B-NB1-A (Blood Derived Normal), aliquot ALCH-B35B-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/703475c9-a053-479b-921e-1be381800621

The open-access MAF lists 60 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 10, Intron 4, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, RNA 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 80/492 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 11/86 reads (13%) | catalogued as rs754135731; called by muse*, mutect2, varscan2*
- F13B | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66375540; called by muse, mutect2
- FAT3 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267603238, COSV53175999; called by muse, mutect2, varscan2
- FNTB | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV99863044; called by muse, mutect2
- IQCH | c.2601G>C p.L867F | Missense Mutation (SNP) | VAF 34/422 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as rs1422348416; called by muse, mutect2
- IRX4 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51471007; called by muse, mutect2
- OSBPL7 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV99136883; called by muse, mutect2
- PAOX | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1472318687, COSV53371964; called by muse, mutect2
- RBM10 | c.2485G>T p.E829* | Nonsense Mutation (SNP) | VAF 45/103 reads (44%) | catalogued as COSV61311914; called by muse, mutect2, varscan2
- RELN | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 91/381 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1452632737, COSV59026898; called by muse, mutect2, varscan2
- SMARCA2 | c.2253G>A p.M751I | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100571419, COSV61806985; called by muse, mutect2
- SPPL2C | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766984781, COSV61294020; called by muse, mutect2, varscan2
- VCAM1 | c.2108A>G p.Y703C | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs375517524; called by muse, mutect2, varscan2
- VPS33B | c.352C>G p.Q118E | Missense Mutation (SNP) | VAF 30/554 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as CM090592; called by muse, mutect2
- VWA5B2 | c.2456C>A p.T819K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs772459643; called by muse, mutect2, varscan2
- ZAP70 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs1559327875; called by muse, mutect2
- ALOX15 | c.496T>A p.F166I | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEACAM16 | c.143T>A p.L48Q | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- CELSR1 | c.7623C>G p.I2541M | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2
- CNR1 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL21A1 | c.161A>C p.E54A | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DHX36 | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.017); called by muse, mutect2
- DNMBP | c.4595T>C p.L1532P | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPN2 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GEMIN5 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.343); called by muse, mutect2
- GNB4 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- GOLGA4 | c.3611T>G p.L1204W | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HECTD2 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- HMGXB4 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HSD17B12 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- KIAA1549 | c.1462_1466del p.R488Yfs*7 | Frame Shift Del (DEL) | VAF 45/207 reads (22%) | called by mutect2, pindel, varscan2
- MRPS16 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2
- PAN3 | c.2548A>G p.I850V | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PHYHD1 | c.246G>C p.E82D | Missense Mutation (SNP) | VAF 28/444 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- PIDD1 | c.1566G>C p.Q522H | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTF1A | c.920G>C p.R307T | Missense Mutation (SNP) | VAF 28/511 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- RGPD4 | c.2115A>C p.Q705H | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- SETD1B | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SIX4 | c.809G>A p.W270* | Nonsense Mutation (SNP) | VAF 38/124 reads (31%) | called by muse, mutect2, varscan2
- STK38L | c.363G>C p.L121F | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- USP48 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- ZNF717 | c.691C>G p.H231D | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.218); called by muse, mutect2
- CAMK1 | c.39G>A p.A13= | Silent (SNP) | VAF 37/177 reads (21%) | catalogued as rs142562247; called by muse, mutect2, varscan2
- MYO5C | c.225C>A p.L75= | Silent (SNP) | VAF 17/316 reads (5%) | called by muse, mutect2
- NPPA | c.455G>A p.*152= | Silent (SNP) | VAF 36/559 reads (6%) | catalogued as rs755829943; called by muse, mutect2
- PKP2 | c.1404G>A p.R468= | Silent (SNP) | VAF 12/201 reads (6%) | called by muse, mutect2
- PRDM13 | c.1947C>G p.V649= | Silent (SNP) | VAF 19/333 reads (6%) | catalogued as rs1406398263; called by muse, mutect2
- SLC22A13 | c.1455C>T p.Y485= | Silent (SNP) | VAF 20/319 reads (6%) | catalogued as rs143948964; called by muse, mutect2
- SPEG | c.3945G>T p.P1315= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1193363646, COSV100404988, COSV56662558; called by muse, mutect2
- SZT2 | c.8031G>A p.A2677= (on ENST00000634258 / NM_001365999.1; = p.A2620= on NM_015284.4) | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as rs138303356; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP12 | c.891C>T p.D297= | Silent (SNP) | VAF 56/261 reads (21%) | called by muse, mutect2, varscan2
- ZNF646 | c.24C>G p.L8= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2
- AC004832.3 | c.*2C>T | 3'UTR (SNP) | VAF 11/256 reads (4%) | called by muse, mutect2
- AC134312.1 | n.347C>T | RNA (SNP) | VAF 13/106 reads (12%) | catalogued as rs760395604; called by muse, mutect2, varscan2
- CDKL1 | c.171+5249G>T | Intron (SNP) | VAF 4/29 reads (14%) | called by muse, varscan2
- ITIH3 | c.1874-50G>A | Intron (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- PTPN21 | c.932+3373G>T | Intron (SNP) | VAF 39/195 reads (20%) | called by muse, mutect2, varscan2
- RNU6-287P | chr17:42894633 C>T | 5'Flank (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- TAP2 | c.1461+38C>T | Intron (SNP) | VAF 17/307 reads (6%) | catalogued as rs750774284; called by muse, mutect2
